Gene-level copy-number profile of tumor specimen TCGA-LI-A9QH-01A from TCGA case TCGA-LI-A9QH, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 72.5 years (26,468 days).
Specimen TCGA-LI-A9QH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.d018b579-f3b9-4f35-819e-5506f2b1e849.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LI-A9QH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 826 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e30cbefa-fbb7-430c-af39-92d8133e1ae2

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 71; copy number 1: 1,277; copy number 2: 18,163; copy number 3: 23,080; copy number 4: 12,632; copy number 5: 3,462; copy number 6: 541; copy number 7: 520; copy number 8: 20; copy number 9: 1; copy number 10: 18; copy number 12: 5; copy number 14: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LI-A9QH-01A-11D-A37B-01): tumor purity 0.91, ploidy 2.97, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 71 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:46,717,423–46,797,420, 2 genes (within-gene range 0–1): AL359880.1, ESD.
- chr13:48,303,744–48,599,436, 1 gene (within-gene range 0–1): RB1.
- chr13:48,389,567–51,200,252, 63 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,421,711–106,443,583, 5 genes: IGHV4-39, IGHV7-40, AC244452.1, IGHVII-40-1, IGHV3-41.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 571 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:196,763–858,091, 8 genes, copy number 10: CHL1, RNU6-1194P, RPS8P6, CHL1-AS1, AC087428.1, LINC01266, RPSAP32, AC090044.1.
- chr3:7,951,263–8,611,924, 1 gene, copy number 7 (within-gene range 4–7): LMCD1-AS1.
- chr3:8,359,344–18,445,588, 218 genes, copy number 7 (broad region; genes not listed).
- chr9:14,475–2,844,095, 42 genes, copy number 7 (within-gene range 2–7): WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, AL358976.1, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279, AL358053.1, AL591644.1, SMARCA2, AL359076.1, RNU2-25P, RN7SL592P, VLDLR-AS1, AL353614.1, VLDLR, AL450467.1, KCNV2, PUM3.
- chr9:16,473,188–16,476,237, 1 gene, copy number 8: AL449983.1.
- chr11:93,661,682–93,730,358, 6 genes, copy number 10–12 (within-gene range 2–12): CEP295, Y_RNA, SCARNA9, AP003499.3, AP003499.2, AP001273.1.
- chr11:93,730,513–93,735,236, 9 genes, copy number 10: SNORA25, SNORA32, SNORD6, SNORA1, SNORA8, SNORD5, SNORA18, MIR1304, SNORA40.
- chr11:108,222,832–108,369,102, 1 gene, copy number 9 (within-gene range 3–14): ATM.
- chr11:108,308,519–108,940,927, 7 genes, copy number 14 (within-gene range 2–14): C11orf65, POGLUT3, EXPH5, DDX10, RPS2P39, AP002453.1, CYCSP29.
- chr15:48,120,990–48,645,721, 12 genes, copy number 7 (within-gene range 1–7): SLC24A5, MYEF2, CTXN2, SLC12A1, AC066612.1, AC066612.2, AC023355.1, Y_RNA, DUT, FBN1, AC022467.2, AC022467.1.
- chr17:1,155,966–2,685,615, 72 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr17:10,383,132–13,601,929, 56 genes, copy number 7: AC005323.2, MYHAS, MYH8, MYH4, MYH1, MYH2, AC005323.1, MYH3, AC002347.1, SCO1, AC002347.2, ADPRM, TMEM220, MAGOH2P, TMEM220-AS1, AC015908.7, AC015908.3, AC015908.1, AC015908.4, AC015908.6, TMEM238L, AC015908.5, PIRT, AC015908.2, RNU6-1065P, RPL15P21, RN7SL601P, AC005548.1, SHISA6, AC005725.1, DNAH9, AC005209.1, AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1, AC005244.2, AC084167.1, LINC00670, AC068442.1, MYOCD, MYOCD-AS1, AC005358.1, ARHGAP44, MIR1269B, AC005274.1, AC005277.2, AC005277.1, ELAC2, AC005303.1, LINC02093, HS3ST3A1, MIR548H3.
- chr17:15,571,491–15,651,653, 1 gene, copy number 7 (within-gene range 5–7): AC005324.2.
- chr17:15,627,960–16,492,193, 46 genes, copy number 7 (within-gene range 5–7): TRIM16, AC005324.4, ZNF29P, ZNF286A, AC005324.3, UBE2SP1, TBC1D26, TBC1D26-AS1, AC005324.5, AC005324.1, CDRT15P2, ZSWIM5P1, RNA5SP436, IL6STP1, MEIS3P1, AC015922.2, AC015922.3, AC015922.1, LINC02087, SPECC1P1, ADORA2B, ZSWIM7, TTC19, AC002553.2, NCOR1, AC002553.1, RPLP1P11, RPL22P21, RNU6-314P, RNU6-862P, RN7SL442P, PIGL, MIR1288, CENPV, UBB, AC093484.3, FTLP12, AC093484.2, TRPV2, AC093484.1, SNHG29, SNORD49B, SNORD49A, AC093484.4, SNORD65, LRRC75A.
- chr18:65,917,782–66,069,647, 2 genes, copy number 7: AC023394.1, PRPF19P1.
- chr19:27,638,483–31,147,981, 70 genes, copy number 7 (broad region; genes not listed).
- chr19:33,283,978–34,066,283, 19 genes, copy number 8: AC008738.6, AC008738.3, CEBPA, AC008738.5, CEBPA-DT, AC008738.2, RPS3AP50, AKR1B1P7, CEBPG, PEPD, AC010485.1, RPL21P131, CHST8, KCTD15, AC008556.1, RN7SL150P, AC016587.1, RPS4XP23, RPS4XP20.

Autosomal genes at a single copy (total copy number 1): 1,277. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
